Somatic mutation profile of tumor specimen TCGA-FS-A1ZC-06A (aliquot TCGA-FS-A1ZC-06A-11D-A197-08) from TCGA case TCGA-FS-A1ZC, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 79.7 years (29,093 days).
Specimen TCGA-FS-A1ZC-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58af1899-1f19-464a-b151-8f806508cafe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A1ZC-10A (Blood Derived Normal), aliquot TCGA-FS-A1ZC-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/784f7fd2-1be4-48de-8495-6e231ab2c48f

The open-access MAF lists 858 somatic variants for this specimen: 538 protein-altering or splice-affecting, 300 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 498, Silent 300, Nonsense Mutation 21, Intron 10, RNA 8, Splice Region 7, Splice Site 7, Frame Shift Del 2, Frame Shift Ins 2, Nonstop Mutation 1, 5'UTR 1, 5'Flank 1.

Variants (750 of 858; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- LDLR | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 82/438 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as rs879254498, CM013557, CM994549, COSV52946475; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- MAP2K2 | c.169T>G p.F57V | Missense Mutation (SNP) | VAF 40/163 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121434498, CM080435, CM086853, COSV53562382, COSV53564387; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NPHS2 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs869025495, CM042093, COSV62634716; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PPP6C | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 24/27 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763733111, COSV65207035; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.2227C>T p.P743S | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.038); catalogued as COSV100229645; called by muse, mutect2, varscan2
- ABCA12 | c.284G>A p.R95K | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as COSV55979542; called by muse, mutect2, varscan2
- ABCA4 | c.1350G>A p.M450I | Missense Mutation (SNP) | VAF 59/211 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1421657735, COSV64679374; called by muse, mutect2, varscan2
- ABCA8 | c.4414G>A p.D1472N | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as COSV52214139; called by muse, mutect2, varscan2
- ABCC5 | c.4231C>T p.P1411S | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760985883, COSV99657883; called by muse, mutect2, varscan2
- ABLIM3 | c.994C>T p.H332Y | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58649878; called by muse, mutect2, varscan2
- ACSL6 | c.1477G>C p.D493H (on ENST00000379240; = p.D518H on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57306589; called by muse, mutect2, varscan2
- ACSM1 | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 58/102 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV54634744; called by muse, varscan2
- ADAM18 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs761055219, COSV55856729; called by muse, mutect2, varscan2
- ADAM29 | c.1223G>A p.G408E | Missense Mutation (SNP) | VAF 90/164 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.133); catalogued as COSV63666072; called by muse, mutect2, varscan2
- ADAM32 | c.1951C>T p.P651S | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65954253; called by muse, mutect2, varscan2
- ADGRF4 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT tolerated (0.71); PolyPhen benign (0.021); catalogued as COSV51950717; called by muse, mutect2, varscan2
- ADGRV1 | c.9586C>T p.P3196S | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV67996906; called by muse, mutect2, varscan2
- ADH1C | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 43/72 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV72463461; called by muse, mutect2, varscan2
- AGGF1 | c.1538C>T p.S513F | Missense Mutation (SNP) | VAF 204/727 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57231534; called by muse, mutect2, varscan2
- AKAP6 | c.4955G>A p.R1652Q | Missense Mutation (SNP) | VAF 30/36 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs763532229, COSV55208487; called by muse, mutect2, varscan2
- ALG8 | c.754T>C p.S252P | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55203583; called by muse, mutect2, varscan2
- ANKRD44 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 43/67 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs925366258, COSV56567963; called by muse, mutect2, varscan2
- APPL1 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs1559510051, COSV55704061; called by muse, mutect2, varscan2
- ARHGAP25 | c.1543G>A p.E515K (on ENST00000409202 / NM_001007231.3; = p.E507K on NM_014882.3) | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.049); catalogued as COSV99772324; called by muse, mutect2, varscan2
- ARHGAP32 | c.212C>T p.T71I | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV59856941; called by muse, mutect2
- ARID2 | c.284+1G>A p.X95_splice | Splice Site (SNP) | VAF 27/50 reads (54%) | catalogued as COSV57608283; called by muse, mutect2, varscan2
- ASB15 | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs1376885076, COSV51929941, COSV99306742; called by muse, mutect2, varscan2
- ASPM | c.4265C>T p.S1422L | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as COSV54141020; called by muse, mutect2, varscan2
- ATG13 | c.1238C>T p.P413L (on ENST00000359513 / NM_001346321.1; = p.P376L on NM_014741.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.642); catalogued as rs1259579138, COSV56322631; called by muse, mutect2, varscan2
- ATP10B | c.1090G>A p.G364S | Missense Mutation (SNP) | VAF 42/66 reads (64%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.873); catalogued as COSV58781817; called by muse, mutect2, varscan2
- ATP13A5 | c.2912C>T p.P971L | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV60876740; called by muse, mutect2
- ATP6V1B1 | c.155T>C p.V52A | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV52272669; called by muse, mutect2, varscan2
- AURKC | c.854C>T p.A285V (on ENST00000302804 / NM_001015878.2; = p.A251V on NM_003160.3) | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV57136974; called by muse, mutect2, varscan2
- B3GAT1 | c.838G>A p.G280R | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV56997876; called by muse, mutect2, varscan2
- BCAS1 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.701); catalogued as COSV65090147; called by muse, mutect2, varscan2
- BCO1 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs535639302, COSV50728006; called by muse, mutect2, varscan2
- BEND6 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV66070727; called by muse, mutect2, varscan2
- BIRC7 | c.526T>G p.S176A | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV53903630; called by muse, mutect2, varscan2
- BMPER | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 80/165 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs764264873, COSV51810889, COSV51817068; called by muse, mutect2, varscan2
- BPTF | c.1804C>T p.L602F | Missense Mutation (SNP) | VAF 86/137 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV58848984; called by muse, mutect2, varscan2
- C10orf67 | c.402A>C p.K134N (on ENST00000323327; = p.K135N on NM_153714.3) | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV60115266; called by muse, mutect2, varscan2
- C1QTNF2 | c.593C>T p.S198L (on ENST00000393975; = p.S153L on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/207 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs761808194, COSV67433426; called by muse, mutect2, varscan2
- C1orf105 | c.460G>A p.G154R | Missense Mutation (SNP) | VAF 239/341 reads (70%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as rs146020107; called by muse, mutect2, varscan2
- C1orf127 | c.514C>G p.Q172E | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV65439323; called by muse, varscan2
- C1orf189 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 55/288 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs201047185; called by muse, mutect2, varscan2
- C1orf56 | c.519C>G p.S173R | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV54849455; called by muse, varscan2
- C2orf78 | c.2381C>T p.P794L | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0.03); PolyPhen benign (0.421); catalogued as COSV68519633; called by muse, mutect2, varscan2
- C3 | c.1432C>T p.R478* | Nonsense Mutation (SNP) | VAF 41/275 reads (15%) | catalogued as CM113003, COSV55576104; called by muse, mutect2, varscan2
- C8A | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV63486849; called by muse, mutect2, varscan2
- CABP5 | c.130C>G p.R44G | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as COSV53152630, COSV53154424; called by muse, mutect2, varscan2
- CACNG2 | c.821G>A p.S274N | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV55642177; called by muse, mutect2, varscan2
- CACNG6 | c.767G>A p.G256E (on ENST00000252729 / NM_145814.1; = p.G185E on NM_031897.2) | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.642); catalogued as COSV53167598; called by muse, varscan2
- CASC3 | c.1606C>T p.P536S | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); catalogued as COSV52869921; called by muse, mutect2, varscan2
- CASKIN2 | c.2863G>A p.E955K | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV58600884; called by muse, mutect2, varscan2
- CCDC141 | c.3502G>A p.G1168S | Missense Mutation (SNP) | VAF 60/114 reads (53%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV55384448; called by muse, mutect2, varscan2
- CCDC141 | c.1768C>T p.P590S | Missense Mutation (SNP) | VAF 48/68 reads (71%) | SIFT tolerated (0.46); PolyPhen benign (0.02); catalogued as COSV55384469; called by muse, mutect2, varscan2
- CCDC146 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as rs200989775, COSV53551982; called by muse, mutect2, varscan2
- CCT8L2 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63464109; called by muse, mutect2, varscan2
- CD163 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63138565; called by muse, mutect2, varscan2
- CD93 | c.530G>A p.G177D | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55669505; called by muse, mutect2, varscan2
- CDH8 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 53/87 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV54906566; called by muse, mutect2, varscan2
- CDHR2 | c.2198G>A p.S733N | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.744); catalogued as COSV56137785; called by muse, mutect2, varscan2
- CDHR2 | c.3784G>A p.E1262K | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV56143811; called by muse, mutect2, varscan2
- CDON | c.2431C>T p.R811C | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs201985321, COSV55002416; called by muse, mutect2, varscan2
- CELSR1 | c.4757C>A p.T1586N | Missense Mutation (SNP) | VAF 48/54 reads (89%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV53101760; called by muse, mutect2, varscan2
- CEP128 | c.2810T>C p.L937P | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55393356; called by muse, mutect2, varscan2
- CFAP221 | c.1484A>T p.K495M | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as COSV99732124, COSV99733351; called by mutect2, varscan2
- CFAP299 | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs142731425; called by mutect2, varscan2
- CFAP61 | c.3698G>A p.W1233* | Nonsense Mutation (SNP) | VAF 99/194 reads (51%) | catalogued as rs543824036, COSV55650568; called by muse, mutect2, varscan2
- CFAP77 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 44/51 reads (86%) | SIFT tolerated (0.33); PolyPhen benign (0.229); catalogued as COSV58018026; called by muse, mutect2, varscan2
- CFAP91 | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56345520; called by muse, mutect2, varscan2
- CHAMP1 | c.2075T>C p.F692S | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555379962, COSV63523490; called by muse, mutect2, varscan2
- CHD3 | c.4073-1G>A p.X1358_splice | Splice Site (SNP) | VAF 40/72 reads (56%) | catalogued as COSV57877790, COSV57881397; called by muse, mutect2, varscan2
- CHD7 | c.373G>T p.V125F | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.987); catalogued as COSV101418583; called by muse, varscan2
- CHI3L1 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55140486; called by muse, mutect2, varscan2
- CHIT1 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774169158, COSV55150267; called by mutect2, varscan2
- CHST11 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.94); catalogued as rs763372855, COSV57996401; called by muse, mutect2, varscan2
- CILP2 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV52281328; called by muse, mutect2, varscan2
- CLCN1 | c.1279T>A p.L427M | Missense Mutation (SNP) | VAF 107/246 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV58375223; called by muse, mutect2, varscan2
- CLPB | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.021); catalogued as COSV53634509; called by muse, mutect2, varscan2
- CLVS2 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 107/122 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV51563090; called by muse, mutect2, varscan2
- CNGA2 | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 35/42 reads (83%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs758699633, COSV61705411; called by muse, mutect2, varscan2
- CNOT3 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55369335; called by muse, mutect2, varscan2
- CNTN2 | c.2762G>A p.W921* | Nonsense Mutation (SNP) | VAF 16/107 reads (15%) | catalogued as COSV59353752; called by muse, mutect2, varscan2
- CNTN4 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 46/77 reads (60%) | SIFT tolerated (0.92); PolyPhen benign (0.081); catalogued as COSV61882376; called by muse, mutect2, varscan2
- CNTN4 | c.2351G>A p.G784E | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs773241153, COSV61882383; called by muse, mutect2, varscan2
- COBLL1 | c.2935G>A p.E979K (on ENST00000392717; = p.E941K on NM_014900.5) | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV52077720; called by muse, mutect2
- COG7 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.596); catalogued as COSV56153839; called by muse, mutect2, varscan2
- COL24A1 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.69); PolyPhen benign (0.06); catalogued as COSV65315968; called by muse, mutect2, varscan2
- COL25A1 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.973); catalogued as COSV67660717; called by muse, varscan2
- COL4A4 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV61637421; called by muse, mutect2, varscan2
- CPA2 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV55981734; called by muse, mutect2, varscan2
- CPED1 | c.2540C>T p.P847L | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60000337; called by muse, mutect2, varscan2
- CPNE4 | c.1484G>A p.G495E | Missense Mutation (SNP) | VAF 49/81 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV70193225; called by muse, mutect2, varscan2
- CRISP2 | c.356T>A p.L119Q | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV59257303; called by muse, mutect2, varscan2
- CSMD1 | c.4459G>A p.D1487N (on ENST00000520002; = p.D1486N on NM_033225.6) | Missense Mutation (SNP) | VAF 54/69 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59326915; called by muse, mutect2, varscan2
- CTTNBP2NL | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs774644437, COSV54747682; called by muse, mutect2, varscan2
- CXCR2 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1298311873, COSV59279763; called by muse, mutect2, varscan2
- CYB5RL | c.455T>C p.M152T | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1172680626, COSV55279706; called by muse, mutect2, varscan2
- CYP2C8 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 27/33 reads (82%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as CM115008, COSV64878951; called by muse, mutect2, varscan2
- CYP2E1 | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 64/79 reads (81%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); catalogued as COSV53315852; called by muse, mutect2, varscan2
- CYP4F8 | c.466C>T p.H156Y | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57855745; called by muse, mutect2, varscan2
- CYP4Z1 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1436665985, COSV61963983; called by muse, mutect2, varscan2
- CYP7A1 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 54/113 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56966275; called by muse, mutect2, varscan2
- CYRIB | c.479G>A p.R160K | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV67833854; called by muse, mutect2, varscan2
- DDX1 | c.1885C>G p.H629D | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV51844238; called by muse, mutect2, varscan2
- DERA | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 34/54 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs745521985, COSV70773798; called by muse, mutect2, varscan2
- DGKD | c.2852C>T p.S951F (on ENST00000264057 / NM_152879.3; = p.S907F on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99897903; called by muse, mutect2, varscan2
- DIP2B | c.2794C>T p.L932F | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56593668; called by muse, mutect2
- DIPK2A | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1237923246, COSV59858464; called by muse, mutect2, varscan2
- DKK4 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 47/248 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.322); catalogued as COSV55184407; called by muse, mutect2, varscan2
- DLGAP4 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs747229357, COSV59424651; called by mutect2, varscan2
- DNAH3 | c.4459G>A p.E1487K | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs539798967, COSV54558236; called by muse, mutect2, varscan2
- DNAH5 | c.13774C>T p.R4592* | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | catalogued as rs758112779, COSV54210253, COSV54253592, COSV99455552; called by muse, varscan2
- DNAH5 | c.5282G>A p.R1761Q | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as rs774020682, COSV54232685; called by muse, mutect2, varscan2
- DNAH5 | c.2780C>T p.S927L | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV54255706; called by muse, varscan2
- DNAI2 | c.1292C>T p.T431I | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV56763268; called by muse, mutect2, varscan2
- DNAJC11 | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53791675; called by muse, mutect2, varscan2
- DNAJC5G | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV56080680, COSV56081314; called by muse, mutect2
- DOCK3 | c.4093C>T p.P1365S | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768190190, COSV56522696; called by muse, mutect2, varscan2
- DPEP3 | c.230C>T p.T77I | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV52053246; called by muse, mutect2, varscan2
- DPPA3 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1241336037, COSV61503764; called by muse, mutect2, varscan2
- DSC1 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.081); catalogued as rs780041445, COSV57152583; called by muse, mutect2, varscan2
- DSCAML1 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as COSV58404829; called by muse, varscan2
- EDEM3 | c.2537C>T p.S846L | Missense Mutation (SNP) | VAF 54/67 reads (81%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.021); catalogued as COSV58928978; called by muse, mutect2, varscan2
- EDNRA | c.137G>A p.S46N | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV60100841; called by muse, mutect2, varscan2
- EMILIN2 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 51/212 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV54422877; called by muse, mutect2, varscan2
- ENPEP | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 54/84 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs774784703, COSV54449632; called by muse, mutect2, varscan2
- ENPEP | c.2014G>A p.D672N | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV54458825; called by muse, mutect2, varscan2
- EPHA10 | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV57627859, COSV57627890; called by muse, mutect2, varscan2
- EPHB6 | c.388C>T p.L130F | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs772826639, COSV67419413; called by muse, mutect2, varscan2
- EPS8L3 | c.761G>A p.G254E | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV62610822; called by muse, mutect2, varscan2
- ERBB4 | c.1523C>T p.S508F | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53599748; called by muse, mutect2, varscan2
- ERICH3 | c.3988G>A p.E1330K | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.94); PolyPhen benign (0.005); catalogued as COSV58621142; called by muse, mutect2, varscan2
- ESPL1 | c.5033C>T p.S1678F | Missense Mutation (SNP) | VAF 41/67 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV57757210; called by muse, mutect2, varscan2
- ESRP1 | c.1628C>T p.S543F | Missense Mutation (SNP) | VAF 218/473 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.921); catalogued as COSV64413208; called by muse, mutect2, varscan2
- ESRRG | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 49/60 reads (82%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV63161188, COSV63176499; called by muse, mutect2, varscan2
- EXOC6B | c.913C>T p.L305= | Splice Region (SNP) | VAF 10/32 reads (31%) | catalogued as rs751201848, COSV55576156; called by muse, mutect2, varscan2
- EXT2 | c.581G>A p.G194E (on ENST00000343631; = p.G227E on NM_000401.3) | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59156286; called by muse, mutect2, varscan2
- EZH2 | c.11C>T p.T4I | Missense Mutation (SNP) | VAF 127/333 reads (38%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.46); catalogued as COSV100237144; called by muse, mutect2, varscan2
- EZH2 | c.10A>C p.T4P | Missense Mutation (SNP) | VAF 125/330 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.46); catalogued as COSV100237147; called by muse, mutect2, varscan2
- F8 | c.4802C>T p.S1601F | Missense Mutation (SNP) | VAF 72/79 reads (91%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV64277420, COSV64279678; called by muse, mutect2, varscan2
- FAM237A | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.805); catalogued as COSV101405608; called by muse, mutect2, varscan2
- FARP2 | c.1673C>T p.T558I | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50885178; called by muse, mutect2, varscan2
- FAT1 | c.5866G>A p.D1956N | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs549753426, COSV71674467; called by muse, mutect2, varscan2
- FAT3 | c.3053C>T p.P1018L | Missense Mutation (SNP) | VAF 305/513 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53134220; called by muse, mutect2, varscan2
- FBXO40 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.6); catalogued as COSV57528460; called by muse, mutect2, varscan2
- FBXW12 | c.1043G>A p.G348E | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV56485886; called by muse, mutect2, varscan2
- FBXW5 | c.1090C>T p.Q364* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as rs965576490, COSV56404272; called by muse, mutect2
- FCMR | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 127/607 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV65569860; called by muse, mutect2, varscan2
- FCRL4 | c.1225C>T p.H409Y | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV54867199; called by muse, mutect2
- FERD3L | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.324); catalogued as rs760870327, COSV51764715; called by mutect2, varscan2
- FGA | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 72/106 reads (68%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs760992799, COSV57392359; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FIBIN | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.475); catalogued as rs755624469, COSV59413716; called by muse, mutect2, varscan2
- FLACC1 | c.275A>T p.N92I | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV53788134; called by muse, mutect2, varscan2
- FLNB | c.2924G>A p.G975E | Missense Mutation (SNP) | VAF 57/105 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1390303574, COSV55892015, COSV99912692; called by muse, mutect2, varscan2
- FMO2 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.073); catalogued as COSV52946876; called by muse, mutect2, varscan2
- FNTA | c.1113T>G p.N371K | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV56491745; called by muse, mutect2
- FOLR1 | c.717G>A p.W239* | Nonsense Mutation (SNP) | VAF 14/67 reads (21%) | catalogued as COSV56617325; called by muse, mutect2, varscan2
- FREM1 | c.3395C>T p.S1132F | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101085721; called by muse, mutect2, varscan2
- FREM2 | c.3496C>T p.R1166C | Missense Mutation (SNP) | VAF 69/127 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as rs201063766, COSV54844085; called by muse, mutect2, varscan2
- FRMD4B | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.3); PolyPhen benign (0.112); catalogued as rs1206138312, COSV68334218; called by muse, mutect2, varscan2
- FRMPD4 | c.1937C>T p.P646L | Missense Mutation (SNP) | VAF 48/58 reads (83%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); catalogued as rs769660304, COSV66224153, COSV66225060; called by muse, mutect2, varscan2
- FUT6 | c.213T>A p.F71L | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54609137; called by mutect2, varscan2
- FUT9 | c.571T>C p.W191R | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56159168; called by muse, mutect2, varscan2
- GABRB2 | c.1430C>T p.T477I (on ENST00000274547; = p.T439I on NM_000813.3) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as rs781122974, COSV50935403; called by muse, mutect2, varscan2
- GABRE | c.1441G>A p.D481N | Missense Mutation (SNP) | VAF 24/26 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64821792; called by muse, mutect2, varscan2
- GALNT14 | c.1555G>A p.D519N | Missense Mutation (SNP) | VAF 54/101 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs150328877; called by muse, mutect2, varscan2
- GALNT17 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs773651456, COSV61160937; called by muse, varscan2
- GARS1 | c.1945G>A p.D649N | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.155); catalogued as rs775471710, COSV66828418; called by mutect2, varscan2
- GBF1 | c.1510A>T p.M504L (on ENST00000369983 / NM_001377137.1; = p.M503L on NM_004193.3) | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV64149778; called by muse, mutect2, varscan2
- GFRAL | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV61232533, COSV61236529; called by muse, mutect2, varscan2
- GHR | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867392523, COSV50109830, COSV50135382; called by muse, mutect2, varscan2
- GIMAP4 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as rs1300064732, COSV55435083; called by muse, mutect2, varscan2
- GIMAP8 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 78/209 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.114); catalogued as COSV56234764; called by muse, mutect2, varscan2
- GLIS3 | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.66); catalogued as COSV101127752, COSV67949645; called by muse, mutect2, varscan2
- GLYATL2 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.089); catalogued as COSV54851884; called by muse, mutect2, varscan2
- GPR158 | c.2815A>G p.K939E | Missense Mutation (SNP) | VAF 106/119 reads (89%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV66285231; called by muse, mutect2, varscan2
- GPR171 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.074); catalogued as rs560925200, COSV56389795; called by muse, mutect2, varscan2
- GPRC5B | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.118); catalogued as COSV56025768, COSV56029128; called by muse, mutect2, varscan2
- GRIA4 | c.885+1G>A p.X295_splice | Splice Site (SNP) | VAF 21/39 reads (54%) | catalogued as COSV56924107, COSV99228210; called by muse, mutect2, varscan2
- GRIP1 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs367635870; called by muse, mutect2, varscan2
- GRM7 | c.2416C>T p.P806S | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63176871; called by muse, mutect2, varscan2
- GRXCR1 | c.869G>A p.G290D | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV67675426; called by muse, mutect2, varscan2
- GUCA1A | c.409G>T p.D137Y | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV50005640; called by muse, mutect2, varscan2
- GUCA1C | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 72/122 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as rs1265768088, COSV51712957; called by muse, mutect2, varscan2
- GUCA2A | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100813034, COSV63691489; called by mutect2, varscan2
- H1-5 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 63/223 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV58901786; called by muse, mutect2, varscan2
- HAP1 | c.1200+1G>A p.X400_splice | Splice Site (SNP) | VAF 11/46 reads (24%) | catalogued as COSV57881253; called by muse, mutect2, varscan2
- HBD | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV53083683; called by muse, mutect2, varscan2
- HCAR2 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.084); catalogued as COSV100186691, COSV61025651; called by muse, mutect2, varscan2
- HECTD4 | c.10364C>T p.P3455L | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV101108434; called by muse, mutect2, varscan2
- HECTD4 | c.6067C>T p.L2023F | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs1265027385, COSV66401229; called by muse, mutect2, varscan2
- HERC1 | c.9437C>T p.S3146F | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.181); catalogued as COSV71250837; called by muse, mutect2, varscan2
- HERC1 | c.4339C>T p.H1447Y | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.838); catalogued as rs7162519, COSV101497083; called by muse, mutect2, varscan2
- HHIP | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs146905204; called by mutect2, varscan2
- HLA-DQA2 | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.242); catalogued as rs769302428, COSV100890820; called by muse, mutect2, varscan2
- HOXA3 | c.955T>A p.C319S | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV57829403; called by muse, mutect2, varscan2
- HS6ST3 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65019986; called by muse, mutect2, varscan2
- HTR5A | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.673); catalogued as rs746794415, COSV55287961; called by muse, mutect2, varscan2
- HYDIN | c.6439C>T p.R2147C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370204963; called by mutect2, varscan2
- IARS2 | c.1743G>A p.E581= | Splice Region (SNP) | VAF 8/60 reads (13%) | catalogued as COSV56965046; called by muse, mutect2, varscan2
- IGLC3 | c.188A>G p.N63S | Missense Mutation (SNP) | VAF 35/42 reads (83%) | PolyPhen benign (0.109); catalogued as rs1431304794; called by muse, mutect2, varscan2
- IGSF1 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 27/30 reads (90%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs776614400, COSV63840964; called by muse, mutect2, varscan2
- IKZF3 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV53108135; called by muse, mutect2, varscan2
- IL27 | c.207G>A p.A69= | Splice Region (SNP) | VAF 12/37 reads (32%) | catalogued as rs764917281, COSV60490121; called by muse, mutect2, varscan2
- IL7R | c.1085G>A p.G362E | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.287); catalogued as COSV57407795, COSV57413989; called by muse, mutect2, varscan2
- IMPG2 | c.3415C>T p.P1139S | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as rs1183768943, COSV51986047; called by muse, varscan2
- INAVA | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1013509036, COSV66257787; called by muse, mutect2, varscan2
- IRAK1 | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 53/59 reads (90%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.805); catalogued as COSV57657756; called by muse, mutect2, varscan2
- ITCH | c.1178C>T p.S393F (on ENST00000262650 / NM_001257137.3; = p.S352F on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.514); catalogued as COSV52938500; called by muse, mutect2, varscan2
- ITGAL | c.1981C>T p.P661S | Missense Mutation (SNP) | VAF 56/105 reads (53%) | SIFT tolerated (0.8); PolyPhen benign (0.012); catalogued as COSV63324826; called by muse, mutect2, varscan2
- ITPKC | c.1862C>T p.S621F | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54577958; called by muse, mutect2, varscan2
- KCNB2 | c.325C>T p.H109Y | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866863463, COSV73049212; called by muse, mutect2, varscan2
- KCNJ15 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1028441815, COSV100154119, COSV60812268; called by muse, mutect2, varscan2
- KCNT2 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 33/48 reads (69%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV54086765, COSV54100416; called by muse, mutect2, varscan2
- KCNV1 | c.560G>C p.G187A | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV52089705, COSV52089755; called by muse, varscan2
- KCTD18 | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.011); catalogued as rs1287920054, COSV63345265; called by muse, mutect2, varscan2
- KDM3B | c.4378C>T p.R1460W | Missense Mutation (SNP) | VAF 50/57 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV58688193; called by muse, mutect2, varscan2
- KDR | c.1526G>A p.G509E | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs866807777, COSV55762852; called by muse, mutect2, varscan2
- KIAA1109 | c.5819C>T p.P1940L | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.244); catalogued as COSV52696806; called by muse, mutect2, varscan2
- KLK7 | c.665G>A p.G222E | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58344993; called by muse, mutect2, varscan2
- KMT2A | c.4396C>T p.P1466S | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV63282023; called by muse, mutect2, varscan2
- KMT2C | c.9977C>T p.P3326L | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as COSV51513476; called by muse, mutect2, varscan2
- KRT1 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1166815949, COSV52870073; called by muse, mutect2, varscan2
- KRT23 | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV52928382; called by muse, mutect2, varscan2
- KRT6B | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1364435295, COSV52887096; called by muse, mutect2
- KRTAP10-8 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555931154, COSV58165797; called by muse, mutect2, varscan2
- KRTAP11-1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 55/62 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV60093929; called by muse, mutect2, varscan2
- LAMB4 | c.5072G>A p.G1691E | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52717679; called by muse, mutect2, varscan2
- LAMP5 | c.603G>A p.M201I | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV55717680; called by muse, mutect2, varscan2
- LHX5 | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV55664517; called by muse, mutect2, varscan2
- LIPI | c.388A>G p.I130V | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT tolerated (0.33); PolyPhen benign (0.101); catalogued as COSV60716945; called by muse, mutect2, varscan2
- LLGL2 | c.75G>A p.K25= | Splice Region (SNP) | VAF 23/62 reads (37%) | catalogued as COSV51418225; called by muse, mutect2, varscan2
- LPAR1 | c.558G>A p.W186* | Nonsense Mutation (SNP) | VAF 60/67 reads (90%) | catalogued as COSV62692283; called by muse, mutect2, varscan2
- LPAR4 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 45/49 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70912676, COSV70913335, COSV70913586; called by muse, mutect2, varscan2
- LRP1B | c.9826C>T p.L3276F | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV67284296; called by muse, mutect2, varscan2
- LRP1B | c.9326G>C p.R3109T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV67188421, COSV67284298; called by muse, mutect2, varscan2
- LRRC7 | c.1166C>T p.S389F (on ENST00000651989 / NM_001370785.2; = p.S356F on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 89/169 reads (53%) | SIFT tolerated (0.93); PolyPhen benign (0.225); catalogued as COSV50653853; called by muse, mutect2, varscan2
- LTBP1 | c.2257G>A p.G753R (on ENST00000404816 / NM_206943.4; = p.G427R on NM_000627.4) | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.107); catalogued as COSV63199281; called by muse, mutect2, varscan2
- MAEL | c.882T>G p.C294W | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV63306663; called by muse, mutect2, varscan2
- MAGEB16 | c.390G>A p.M130I | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as COSV67873931; called by muse, mutect2, varscan2
- MAGEC1 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs763107911, COSV53580431; called by muse, mutect2, varscan2
- MAGI3 | c.2567G>A p.R856Q | Missense Mutation (SNP) | VAF 120/383 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56829478, COSV56840127; called by muse, mutect2, varscan2
- MAN1A1 | c.1213C>T p.H405Y | Missense Mutation (SNP) | VAF 27/35 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1219038012, COSV63789801; called by muse, mutect2, varscan2
- MAP1B | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57107772; called by muse, mutect2, varscan2
- MAP4K3 | c.2558C>T p.S853L | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55717725; called by muse, varscan2
- MAPK10 | c.985G>T p.E329* (on ENST00000359221 / NM_001351625.2; = p.E367* on NM_002753.5) | Nonsense Mutation (SNP) | VAF 36/124 reads (29%) | catalogued as COSV60376282, COSV60395978; called by muse, mutect2, varscan2
- MAPT | c.1354C>T p.R452C (on ENST00000262410 / NM_001377265.1; = p.R126C on NM_005910.5) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1042556084, COSV52240103; called by muse, mutect2
- ME3 | c.1511G>A p.G504E | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); catalogued as COSV62772241; called by muse, mutect2, varscan2
- MECOM | c.1841G>A p.G614E (on ENST00000468789 / NM_001105078.4; = p.G802E on NM_004991.4) | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.113); catalogued as rs139044661, COSV52962683; called by muse, mutect2, varscan2
- MEST | c.543T>A p.F181L | Missense Mutation (SNP) | VAF 147/744 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as COSV56230180; called by muse, mutect2, varscan2
- MET | c.3037C>T p.P1013S | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.185); catalogued as COSV59259679; called by muse, mutect2, varscan2
- MFSD12 | c.995A>G p.K332R | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.363); catalogued as COSV61536977; called by muse, mutect2
- MFSD12 | c.993G>A p.M331I | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.055); catalogued as rs1234862078, COSV61536982; called by muse, mutect2
- MGAM | c.5161G>A p.E1721K | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.023); catalogued as COSV72076120; called by muse, mutect2, varscan2
- MICAL2 | c.2873G>A p.G958E | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV56327585; called by muse, mutect2, varscan2
- MKI67 | c.5464C>T p.R1822C | Missense Mutation (SNP) | VAF 100/114 reads (88%) | SIFT deleterious (0.03); PolyPhen benign (0.347); catalogued as rs750568118, COSV64072852; called by muse, mutect2, varscan2
- MME | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 57/98 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV64706457; called by muse, mutect2, varscan2
- MMP12 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100405119; called by muse, mutect2, varscan2
- MMP26 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 55/87 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV56174362; called by muse, mutect2, varscan2
- MNDA | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 67/94 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as COSV63742295; called by muse, mutect2, varscan2
- MTUS2 | c.1982C>T p.S661L | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.495); catalogued as rs771233147, COSV70912331; called by muse, mutect2
- MUC16 | c.39655T>C p.C13219R | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV66694710, COSV66697498; called by muse, mutect2, varscan2
- MUC16 | c.27379C>T p.P9127S | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.07); catalogued as rs766540693, COSV67500934; called by muse, mutect2, varscan2
- MUC16 | c.21026C>T p.S7009F | Missense Mutation (SNP) | VAF 164/388 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV67450400, COSV67455274; called by muse, mutect2, varscan2
- MUC16 | c.11962G>A p.E3988K | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.027); catalogued as COSV67468123; called by muse, mutect2, varscan2
- MUC16 | c.2876C>T p.S959F | Missense Mutation (SNP) | VAF 108/249 reads (43%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV67500964; called by muse, mutect2, varscan2
- MUC21 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 65/131 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.302); catalogued as COSV66222442; called by muse, mutect2, varscan2
- MUC4 | c.2585G>A p.G862E | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated, low confidence (0.26); PolyPhen probably damaging (0.934); catalogued as COSV62194652; called by muse, mutect2, varscan2
- MYH13 | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 8/17 reads (47%) | catalogued as COSV52846067; called by muse, mutect2, varscan2
- MYO1H | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60452086; called by muse, mutect2, varscan2
- MYO5B | c.4502C>T p.P1501L | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV53232837; called by muse, varscan2
- MYOC | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 80/112 reads (71%) | SIFT tolerated (0.18); PolyPhen benign (0.185); catalogued as COSV50680889; called by muse, mutect2, varscan2
- MYOM1 | c.2951G>A p.R984K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs1482537072, COSV55302766; called by muse, mutect2, varscan2
- NBEA | c.5309C>T p.P1770L | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.006); catalogued as COSV100084134, COSV59830408; called by muse, mutect2, varscan2
- NCF4 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 71/81 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as rs754272966, COSV50629795; called by muse, mutect2, varscan2
- NCKAP5 | c.3488G>A p.S1163N | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV58480267; called by muse, mutect2, varscan2
- NEXN | c.1114G>A p.G372R | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.53); catalogued as COSV57361519; called by muse, mutect2
- NLRC3 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs1386739676, COSV57096803; called by muse, mutect2, varscan2
- NLRP13 | c.2725G>A p.D909N | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs267605702, COSV61623167; called by muse, mutect2, varscan2
- NLRP13 | c.2410G>A p.A804T | Missense Mutation (SNP) | VAF 61/118 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61623642; called by muse, mutect2, varscan2
- NLRP2 | c.1187C>T p.S396L | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs371887051, COSV54760313; called by mutect2, varscan2
- NLRP5 | c.2246C>T p.S749F | Missense Mutation (SNP) | VAF 120/290 reads (41%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV66767994; called by muse, mutect2, varscan2
- NLRP6 | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 85/133 reads (64%) | SIFT tolerated (0.22); PolyPhen benign (0.115); catalogued as COSV100381246; called by muse, mutect2, varscan2
- NLRP8 | c.1408G>A p.G470S | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV52595257; called by muse, mutect2, varscan2
- NOL4 | c.314T>C p.V105A | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV52364901; called by muse, mutect2, varscan2
- NOTCH4 | c.2467G>A p.D823N | Missense Mutation (SNP) | VAF 65/237 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.519); catalogued as COSV100901229; called by muse, mutect2, varscan2
- NOVA1 | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 21/25 reads (84%) | catalogued as COSV57489610; called by muse, mutect2, varscan2
- NOX1 | c.1210G>A p.G404R | Missense Mutation (SNP) | VAF 13/13 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54197102; called by muse, mutect2, varscan2
- NPAS4 | c.1597C>T p.P533S | Missense Mutation (SNP) | VAF 104/192 reads (54%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV60650554; called by muse, mutect2, varscan2
- NPY5R | c.743G>A p.R248K | Missense Mutation (SNP) | VAF 58/92 reads (63%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV58454263; called by muse, mutect2, varscan2
- NR5A2 | c.1063T>C p.S355P (on ENST00000367362 / NM_205860.3; = p.S309P on NM_003822.5) | Missense Mutation (SNP) | VAF 32/213 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV99371820; called by muse, mutect2, varscan2
- NRG1 | c.1760C>T p.P587L (on ENST00000405005 / NM_013964.5; = p.P592L on NM_013956.5) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55149643; called by muse, mutect2, varscan2
- NRG2 | c.1760C>T p.P587L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99183549; called by muse, mutect2, varscan2
- NRG2 | c.1759C>T p.P587S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99183552; called by muse, mutect2, varscan2
- NSD1 | c.2111T>A p.I704N | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.071); catalogued as COSV61786347; called by muse, mutect2, varscan2
- NSD2 | c.62T>G p.M21R | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56386371, COSV56397770; called by muse, mutect2, varscan2
- OBSCN | c.8416G>A p.E2806K | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.977); catalogued as COSV52761888, COSV99486047; called by muse, mutect2
- OGDHL | c.2725G>A p.E909K | Missense Mutation (SNP) | VAF 64/77 reads (83%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV65101777; called by muse, varscan2
- OLFML2B | c.1507G>A p.G503R | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.786); catalogued as COSV54201158; called by muse, mutect2, varscan2
- ONECUT1 | c.1025C>T p.S342F | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59951310; called by muse, mutect2, varscan2
- OR10J3 | c.958G>A p.G320S | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV59953599, COSV59953705; called by muse, mutect2, varscan2
- OR10K1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 34/221 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs188612034, COSV56870795, COSV56872483; called by muse, mutect2, varscan2
- OR2A4 | c.647C>T p.S216L | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100199746; called by muse, mutect2, varscan2
- OR2C1 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 77/139 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV59241570; called by muse, mutect2, varscan2
- OR2L3 | c.491A>C p.H164P | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV100742084; called by muse, mutect2, varscan2
- OR2L8 | c.491A>C p.H164P | Missense Mutation (SNP) | VAF 18/290 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV61728773; called by muse, mutect2
- OR2M3 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 82/444 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV71759364; called by muse, mutect2, varscan2
- OR2M5 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 39/240 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as rs749039050, COSV63545850; called by muse, mutect2, varscan2
- OR2T27 | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as rs1269929469, COSV61283903; called by muse, varscan2
- OR2T27 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV61280972; called by muse, varscan2
- OR2T33 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 108/127 reads (85%) | SIFT tolerated (0.24); PolyPhen benign (0.119); catalogued as COSV58818234; called by muse, mutect2, varscan2
- OR4A16 | c.29T>A p.F10Y | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.958); catalogued as COSV100125334, COSV59045435; called by mutect2, varscan2
- OR4A5 | c.741T>A p.F247L | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV60525117; called by mutect2, varscan2
- OR4C12 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 71/125 reads (57%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.646); catalogued as COSV58861381; called by muse, mutect2, varscan2
- OR52D1 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.656); catalogued as COSV59488573; called by mutect2, varscan2
- OR52M1 | c.932G>A p.R311K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64171475, COSV64173116; called by muse, mutect2
- OR5AN1 | c.126G>A p.W42* | Nonsense Mutation (SNP) | VAF 62/112 reads (55%) | catalogued as rs866705032, COSV58323093; called by muse, mutect2, varscan2
- OR5AN1 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs868511922, COSV58322024; called by muse, mutect2, varscan2
- OR5H14 | c.610G>A p.G204S | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs749852815, COSV71194639; called by muse, mutect2, varscan2
- OR5H6 | c.202G>A p.D68N (on ENST00000642105; = p.D52N on NM_001005479.2) | Missense Mutation (SNP) | VAF 138/225 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as COSV67352202; called by muse, mutect2, varscan2
- OR5I1 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as COSV56885670; called by muse, mutect2, varscan2
- OR6C65 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.168); catalogued as COSV65568338; called by muse, mutect2, varscan2
- OR6K3 | c.439C>T p.R147C (on ENST00000368146; = p.R131C on NM_001005327.2) | Missense Mutation (SNP) | VAF 35/203 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as rs748128044, COSV63745210; called by muse, mutect2, varscan2
- OR6T1 | c.959G>A p.S320N | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.038); catalogued as COSV58309984; called by muse, mutect2, varscan2
- OR6T1 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58310000; called by muse, mutect2, varscan2
- OR8D1 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1459721658, COSV100766689; called by muse, mutect2, varscan2
- OR8D2 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100659130, COSV62488279; called by muse, mutect2, varscan2
- OR8I2 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV100136117, COSV56171031; called by muse, mutect2, varscan2
- OTOGL | c.1297G>A p.D433N (on ENST00000547103; = p.D424N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV101509538; called by muse, mutect2, varscan2
- PACRG | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 40/52 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100435308, COSV61323730; called by muse, mutect2, varscan2
- PACRGL | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 61/211 reads (29%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as rs561830924, COSV54845088; called by muse, mutect2, varscan2
- PAM | c.1397C>T p.S466F | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV57221211; called by muse, varscan2
- PAPPA2 | c.3490G>A p.D1164N | Missense Mutation (SNP) | VAF 41/218 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369624348; called by muse, mutect2, varscan2
- PARD3 | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV60764902; called by muse, mutect2, varscan2
- PARM1 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV56655813; called by muse, mutect2, varscan2
- PATE1 | c.236G>A p.R79K | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.026); catalogued as COSV59825252; called by muse, mutect2, varscan2
- PCDH19 | c.787A>C p.S263R | Missense Mutation (SNP) | VAF 49/58 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV55273203; called by muse, mutect2, varscan2
- PCDHA10 | c.952C>T p.H318Y | Missense Mutation (SNP) | VAF 37/41 reads (90%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV56516906; called by muse, mutect2, varscan2
- PCDHA12 | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 54/60 reads (90%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.572); catalogued as COSV56504501; called by muse, varscan2
- PCDHA12 | c.1067C>T p.S356L | Missense Mutation (SNP) | VAF 41/47 reads (87%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.292); catalogued as rs1030865953, COSV56496246; called by muse, varscan2
- PCDHA2 | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.276); catalogued as rs781879420, COSV65369803; called by muse, mutect2, varscan2
- PCDHB15 | c.1808C>T p.S603L | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs1554292207, COSV99179319; called by muse, mutect2, varscan2
- PCDHGA5 | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.05); catalogued as rs937776299, COSV53998107; called by muse, mutect2, varscan2
- PCED1B | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71394915; called by muse, mutect2, varscan2
- PCSK1 | c.1197-2A>C p.X399_splice | Splice Site (SNP) | VAF 21/79 reads (27%) | catalogued as COSV60737953; called by muse, mutect2, varscan2
- PCSK9 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 189/345 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56165576; called by muse, mutect2, varscan2
- PDE4A | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs1214475711, COSV53363818; called by muse, mutect2, varscan2
- PDGFRB | c.2384C>T p.S795F | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1285503815, COSV55810926; called by muse, mutect2, varscan2
- PDZD2 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as rs867931191, COSV56875732; called by muse, mutect2, varscan2
- PEG3 | c.3025A>G p.S1009G | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.423); catalogued as COSV99690873; called by muse, mutect2
- PEX5L | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs374485695; called by muse, mutect2, varscan2
- PGBD4 | c.1720C>T p.P574S | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as COSV56629496; called by muse, mutect2, varscan2
- PGGT1B | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.093); catalogued as COSV99686081; called by muse, mutect2, varscan2
- PGK2 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 66/164 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV59165964; called by muse, mutect2, varscan2
- PGLYRP2 | c.886C>T p.L296F | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52998627; called by muse, varscan2
- PIK3CG | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT tolerated (0.57); PolyPhen benign (0.062); catalogued as rs1183980892, COSV63245183, COSV63254551; called by muse, mutect2, varscan2
- PIK3R5 | c.327C>G p.Y109* | Nonsense Mutation (SNP) | VAF 61/100 reads (61%) | catalogued as COSV52659673; called by muse, mutect2, varscan2
- PKHD1L1 | c.3287C>T p.S1096L | Missense Mutation (SNP) | VAF 84/406 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as rs1423918896, COSV65748745; called by muse, mutect2, varscan2
- PKHD1L1 | c.3836G>A p.G1279E | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.175); catalogued as rs867986792, COSV65741514; called by muse, mutect2, varscan2
- PKHD1L1 | c.11575T>G p.F3859V | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV65755653; called by muse, mutect2, varscan2
- PLB1 | c.2284C>T p.P762S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as COSV100215591; called by muse, mutect2, varscan2
- PLB1 | c.2573G>A p.G858E | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59837651; called by muse, mutect2, varscan2
- PLCD4 | c.2057C>A p.T686K | Missense Mutation (SNP) | VAF 61/230 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV68746295; called by muse, mutect2, varscan2
- PLCG2 | c.3570G>A p.L1190= | Splice Region (SNP) | VAF 20/75 reads (27%) | catalogued as COSV63877715; called by muse, mutect2, varscan2
- PLCL2 | c.457C>T p.R153C (on ENST00000615277 / NM_001144382.2; = p.R27C on NM_015184.5) | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1462336512, COSV67620691; called by muse, mutect2, varscan2
- PLEKHM1 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV69599557; called by muse, mutect2, varscan2
- PLXDC2 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 30/37 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs745577270, COSV65924513; called by muse, mutect2, varscan2
- PLXNA1 | c.1400C>T p.P467L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV52533710; called by muse, mutect2, varscan2
- PLXNA4 | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58166107; called by muse, varscan2
- PMEL | c.1535T>C p.L512P | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59389176; called by muse, mutect2, varscan2
- PNISR | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 32/38 reads (84%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV65080992; called by muse, mutect2, varscan2
- POTEF | c.2719G>A p.E907K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.805); catalogued as rs1357344938, COSV100665466; called by muse, mutect2, varscan2
- PPARG | c.1154G>A p.R385Q (on ENST00000287820 / NM_015869.5; = p.R355Q on NM_005037.7) | Missense Mutation (SNP) | VAF 335/601 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs140204299; called by muse, mutect2, varscan2
- PPFIA2 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs775868568, COSV61018791, COSV61037432; called by mutect2, varscan2
- PREPL | c.1717C>T p.P573S | Missense Mutation (SNP) | VAF 52/94 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53219824; called by muse, mutect2, varscan2
- PRKCA | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV66101672; called by muse, mutect2, varscan2
- PRLR | c.1226G>A p.G409D | Missense Mutation (SNP) | VAF 61/231 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV51501426; called by muse, mutect2, varscan2
- PROM2 | c.1114+2T>C p.X372_splice | Splice Site (SNP) | VAF 25/62 reads (40%) | catalogued as COSV58301293; called by muse, mutect2, varscan2
- PRPF3 | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 288/396 reads (73%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.701); catalogued as rs1448830296, COSV61396557; called by muse, mutect2, varscan2
- PRRG1 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as rs781900371, COSV66156762, COSV66158920; called by muse, mutect2, varscan2
- PTPN9 | c.1273C>T p.R425* | Nonsense Mutation (SNP) | VAF 66/145 reads (46%) | catalogued as rs770114056, COSV60723262; called by muse, mutect2, varscan2
- PTPRC | c.523C>T p.H175Y | Missense Mutation (SNP) | VAF 50/316 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0.038); catalogued as rs758362738, COSV61417558, COSV61421668; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRE | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 29/31 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54560375; called by muse, mutect2, varscan2
- RAB11FIP1 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 188/482 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as rs1214737473, COSV54759010; called by muse, mutect2, varscan2
- RAD54B | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 113/269 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.546); catalogued as rs767848832, COSV60255611; called by muse, mutect2, varscan2
- RAG2 | c.661G>A p.G221R | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57557422; called by muse, mutect2, varscan2
- RAPGEFL1 | c.710A>T p.E237V | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV52865294; called by muse, mutect2, varscan2
- RBMS2 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV56266205; called by muse, mutect2, varscan2
- RIC3 | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 61/92 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58304680, COSV58305522; called by muse, mutect2, varscan2
- RIPOR3 | c.911G>A p.G304D | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1015815551, COSV50409242; called by muse, mutect2, varscan2
- RP1 | c.680T>G p.F227C | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55128874; called by muse, mutect2, varscan2
- RPTN | c.2335G>A p.E779K | Missense Mutation (SNP) | VAF 133/798 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs1019810114, COSV60166727; called by muse, mutect2, varscan2
- RSF1 | c.2530C>T p.R844* | Nonsense Mutation (SNP) | VAF 37/123 reads (30%) | catalogued as COSV57836823; called by muse, mutect2, varscan2
- RTN4RL1 | c.322G>C p.G108R | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58678874; called by muse, mutect2, varscan2
- RUFY4 | c.1078G>A p.G360R | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.621); catalogued as COSV60247548; called by muse, mutect2
- SACS | c.7394C>T p.S2465L | Missense Mutation (SNP) | VAF 53/80 reads (66%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as rs747676277, COSV66533758; called by muse, mutect2, varscan2
- SATB2 | c.1474C>G p.Q492E | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53491634, COSV53493989; called by muse, mutect2, varscan2
- SCEL | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV62994761; called by muse, mutect2, varscan2
- SCN11A | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 44/196 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); catalogued as COSV56578078; called by muse, mutect2, varscan2
- SCN11A | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV56579898; called by muse, mutect2, varscan2
- SDC2 | c.306+1G>A p.X102_splice | Splice Site (SNP) | VAF 11/72 reads (15%) | catalogued as rs1157580638, COSV56232913; called by muse, mutect2, varscan2
- SEC63 | c.627C>T p.G209= | Splice Region (SNP) | VAF 12/27 reads (44%) | catalogued as COSV64602597; called by muse, mutect2, varscan2
- SEMA6A | c.195C>G p.N65K | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV57319094; called by muse, mutect2, varscan2
- SERPINA7 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 41/46 reads (89%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV59667230; called by muse, mutect2, varscan2
- SERPINA9 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 30/37 reads (81%) | SIFT tolerated (0.14); PolyPhen benign (0.041); catalogued as rs775122463, COSV54079282; called by muse, mutect2, varscan2
- SERPINB2 | c.1207A>C p.T403P | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV53076186; called by muse, mutect2, varscan2
- SHANK1 | c.6056C>T p.S2019F | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53264674; called by muse, mutect2
- SHOC1 | c.665A>G p.E222G | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as rs745813921, COSV59507960; called by muse, mutect2, varscan2
- SHPK | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV56650807; called by muse, mutect2
- SIGLEC6 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1224241402, COSV58434515; called by muse, mutect2, varscan2
- SLC12A5 | c.275C>T p.T92I (on ENST00000454036 / NM_001134771.2; = p.T69I on NM_020708.5) | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV54803447; called by muse, mutect2, varscan2
- SLC25A20 | c.555G>A p.M185I | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.021); catalogued as rs1339148392, COSV59805075; called by mutect2, varscan2
- SLC5A11 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 83/139 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as COSV61740137, COSV61744012; called by muse, mutect2, varscan2
- SLC6A1 | c.983C>T p.S328L | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779431997, COSV55114077; called by muse, mutect2, varscan2
- SLCO5A1 | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 48/86 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52670023; called by muse, varscan2
- SMAD2 | c.749C>T p.S250F | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.27); catalogued as COSV51067610; called by muse, mutect2, varscan2
- SMARCA2 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV61813976; called by muse, mutect2, varscan2
- SNTG1 | c.220G>A p.G74R | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52478396; called by muse, mutect2
- SNTG2 | c.75G>A p.T25= | Splice Region (SNP) | VAF 18/97 reads (19%) | catalogued as rs758466394, COSV57976035; called by muse, mutect2, varscan2
- SNURF | c.66A>T p.E22D | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.027); catalogued as COSV100578462, COSV57601298; called by mutect2, varscan2
- SPATA22 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.297); catalogued as COSV52155060; called by mutect2, varscan2
- SPATA31D1 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 26/30 reads (87%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV61202303; called by muse, mutect2, varscan2
- SPATA46 | c.31G>A p.G11R | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.204); catalogued as COSV63397200; called by muse, mutect2
- SPEN | c.10033C>T p.P3345S | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs1185452757, COSV65267813; called by muse, mutect2, varscan2
- SPEN | c.10034C>T p.P3345L | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as rs35291379, COSV100999080; called by muse, mutect2, varscan2
- SPESP1 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1286638245, COSV52997460; called by muse, mutect2, varscan2
- SPO11 | c.1111C>T p.Q371* | Nonsense Mutation (SNP) | VAF 34/122 reads (28%) | catalogued as COSV61997010; called by muse, mutect2, varscan2
- SPOCK3 | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62730151; called by muse, mutect2, varscan2
- SRRM2 | c.5291C>T p.S1764L | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs1487628161, COSV57070397; called by muse, mutect2, varscan2
- ST8SIA4 | c.313G>A p.G105S | Missense Mutation (SNP) | VAF 31/101 reads (31%) | PolyPhen probably damaging (0.999); catalogued as COSV51517972; called by muse, mutect2, varscan2
- STIM1 | c.1550C>T p.T517I | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.276); catalogued as COSV56161617; called by muse, mutect2, varscan2
- STX5 | c.683G>A p.G228D | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT tolerated (0.66); PolyPhen benign (0.059); catalogued as rs1361193779, COSV53682514; called by muse, mutect2
- STXBP5 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51659320; called by muse, mutect2, varscan2
- SYDE2 | c.3584G>C p.*1195Sext*2 | Nonstop Mutation (SNP) | VAF 8/13 reads (62%) | catalogued as COSV58326431; called by muse, mutect2, varscan2
- SYNE1 | c.157C>T p.L53F | Missense Mutation (SNP) | VAF 49/60 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55127078; called by muse, mutect2, varscan2
- SYNJ2 | c.3296C>T p.P1099L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV62901387; called by muse, varscan2
- TAB1 | c.1223C>T p.S408F | Missense Mutation (SNP) | VAF 53/57 reads (93%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV53372293; called by muse, mutect2, varscan2
- TACC2 | c.3155C>T p.A1052V | Missense Mutation (SNP) | VAF 28/33 reads (85%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV57776524; called by muse, varscan2
- TACC2 | c.3200G>A p.S1067N | Missense Mutation (SNP) | VAF 28/34 reads (82%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV57776542; called by muse, varscan2
- TACR1 | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 92/155 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs199512029, COSV59485522; called by muse, mutect2, varscan2
- TAFA5 | c.388A>C p.T130P (on ENST00000402357 / NM_001082967.3; = p.T123P on NM_015381.7) | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV60997682; called by muse, mutect2, varscan2
- TBC1D2 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 17/19 reads (89%) | SIFT tolerated (0.18); PolyPhen benign (0.138); catalogued as COSV59789633; called by muse, mutect2, varscan2
- TBC1D22B | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV65142941; called by muse, mutect2, varscan2
- TBC1D8B | c.1502C>T p.S501L | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV52184392; called by muse, mutect2, varscan2
- TCOF1 | c.895C>T p.Q299* (on ENST00000377797 / NM_001135243.1; = p.Q222* on NM_000356.4) | Nonsense Mutation (SNP) | VAF 3/9 reads (33%) | catalogued as COSV60355675; called by muse, mutect2, varscan2
- TCOF1 | c.1859G>A p.S620N (on ENST00000377797 / NM_001135243.1; = p.S543N on NM_000356.4) | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.459); catalogued as COSV60355688; called by muse, mutect2, varscan2
- TDRD5 | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as COSV54241692; called by muse, mutect2, varscan2
- TDRKH | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 47/227 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64316040; called by muse, mutect2, varscan2
- TEAD4 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as rs1239272473, COSV100622070; called by muse, mutect2
- TECTA | c.2765C>T p.S922F | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs759235643, COSV50688287; called by muse, mutect2, varscan2
- TEK | c.2418G>C p.K806N | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66236219; called by muse, mutect2, varscan2
- TENM1 | c.776G>A p.R259K | Missense Mutation (SNP) | VAF 80/94 reads (85%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.695); catalogued as rs1225488921, COSV64446675; called by muse, mutect2, varscan2
- TESK2 | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 34/167 reads (20%) | catalogued as rs375688752; called by muse, mutect2, varscan2
- TESPA1 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as COSV57262048; called by muse, mutect2
- TEX14 | c.3880G>T p.A1294S (on ENST00000240361 / NM_001201457.2; = p.A1248S on NM_031272.5) | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV53628312; called by muse, mutect2, varscan2
- THAP12 | c.1932T>G p.C644W | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV52613657; called by muse, mutect2, varscan2
- THBS1 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.989); catalogued as COSV52956418; called by muse, mutect2, varscan2
- TLL1 | c.2230G>A p.E744K | Missense Mutation (SNP) | VAF 50/82 reads (61%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.986); catalogued as rs1165249462, COSV50261280; called by muse, mutect2, varscan2
- TLR7 | c.1750G>A p.G584R | Missense Mutation (SNP) | VAF 59/70 reads (84%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66125414; called by muse, mutect2, varscan2
- TMEM132B | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as rs1184028441, COSV54762300; called by muse, mutect2, varscan2
- TMEM200A | c.1454G>A p.G485E | Missense Mutation (SNP) | VAF 31/32 reads (97%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV51661010; called by muse, mutect2, varscan2
- TMEM248 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.069); catalogued as rs868859750, COSV58578682; called by muse, mutect2, varscan2
- TNFRSF21 | c.1862C>T p.A621V | Missense Mutation (SNP) | VAF 86/230 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57285648; called by muse, mutect2, varscan2
- TNIK | c.3529C>T p.H1177Y | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV52699166; called by mutect2, varscan2
- TNN | c.1097C>T p.S366F | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV53437781; called by muse, mutect2, varscan2
- TNXB | c.2517G>A p.M839I | Missense Mutation (SNP) | VAF 55/242 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.339); catalogued as COSV64490679; called by muse, mutect2, varscan2
- TPO | c.455G>A p.R152K | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61112936; called by muse, mutect2, varscan2
- TPP1 | c.1066T>C p.F356L | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV54995550; called by muse, mutect2, varscan2
- TPTE | c.1037G>A p.G346E (on ENST00000618007 / NM_199261.4; = p.G328E on NM_199259.4) | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752996568; called by muse, mutect2, varscan2
- TREML4 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 41/218 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.103); catalogued as COSV58386727; called by muse, mutect2, varscan2
- TRGV8 | c.71G>C p.G24A | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.915); catalogued as rs754994401; called by muse, varscan2
- TRIM55 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV52551628; called by muse, mutect2, varscan2
- TRPC5 | c.1484C>T p.S495F | Missense Mutation (SNP) | VAF 32/33 reads (97%) | SIFT tolerated (0.16); PolyPhen benign (0.329); catalogued as COSV53304832; called by muse, mutect2, varscan2
- TRPM5 | c.2312T>G p.L771R | Missense Mutation (SNP) | VAF 88/272 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV50214741; called by muse, mutect2, varscan2
- TRPV6 | c.395T>G p.L132R | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); catalogued as COSV63894104; called by muse, mutect2, varscan2
- TSHZ3 | c.2683C>T p.Q895* | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | catalogued as COSV53685543; called by muse, mutect2, varscan2
- TSPYL5 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.99); PolyPhen benign (0.089); catalogued as rs773978290, COSV59073142; called by muse, mutect2, varscan2
- TTC39C | c.382C>T p.R128W (on ENST00000317571 / NM_001135993.2; = p.R67W on NM_153211.4) | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs925105160, COSV100455151, COSV58221724; called by muse, mutect2, varscan2
- TTLL11 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 94/111 reads (85%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.653); catalogued as COSV58654476; called by muse, mutect2, varscan2
- TTN | c.47585G>A p.G15862D (on ENST00000591111; = p.G8438D on NM_003319.4) | Missense Mutation (SNP) | VAF 19/30 reads (63%) | PolyPhen probably damaging (1); catalogued as COSV60405694; called by muse, mutect2, varscan2
- TTN | c.39829G>A p.D13277N (on ENST00000591111; = p.D5853N on NM_003319.4) | Missense Mutation (SNP) | VAF 34/112 reads (30%) | PolyPhen probably damaging (0.998); catalogued as COSV60405725; called by muse, mutect2, varscan2
- TTN | c.33919G>A p.E11307K (on ENST00000591111; = p.E10380K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | PolyPhen benign (0); catalogued as rs557526069, COSV60308894, COSV60405757; called by muse, mutect2
- TTN | c.31994C>T p.S10665L (on ENST00000591111; = p.S9738L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/54 reads (56%) | PolyPhen benign (0.001); catalogued as COSV60405768; called by muse, mutect2, varscan2
- TTN | c.28847C>T p.S9616L (on ENST00000591111; = p.S8689L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | PolyPhen probably damaging (0.996); catalogued as rs764352461, COSV59947005; called by mutect2, varscan2
- TTN | c.26341G>A p.G8781S (on ENST00000591111; = p.G7854S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/98 reads (61%) | PolyPhen probably damaging (0.999); catalogued as rs772115815, COSV59891790; called by muse, mutect2, varscan2
- TTN | c.25930C>T p.H8644Y (on ENST00000591111; = p.H7717Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/27 reads (48%) | PolyPhen benign (0.003); catalogued as COSV60405810; called by muse, mutect2, varscan2
- TTN | c.18031G>A p.D6011N (on ENST00000591111; = p.D5084N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | PolyPhen possibly damaging (0.856); catalogued as COSV60395533; called by mutect2, varscan2
- TTN | c.16978G>A p.E5660K (on ENST00000591111; = p.E4733K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/119 reads (59%) | PolyPhen probably damaging (0.994); catalogued as COSV59888398; called by muse, mutect2, varscan2
- UHRF1BP1L | c.3091C>T p.L1031F | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV54443665; called by muse, mutect2, varscan2
- UNC13B | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 39/44 reads (89%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.039); catalogued as rs765577061, COSV65939542; called by muse, mutect2, varscan2
- UNC13C | c.1163A>G p.D388G | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); catalogued as COSV52932980; called by muse, mutect2, varscan2
- UNC5B | c.1001G>A p.G334E | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1487565068, COSV58978455; called by muse, mutect2, varscan2
- UNC5C | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 44/72 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs201199826, COSV71659049; called by muse, mutect2, varscan2
- USH2A | c.9385G>A p.D3129N | Missense Mutation (SNP) | VAF 78/108 reads (72%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV56407602, COSV56451594; called by muse, mutect2, varscan2
- USP36 | c.1979C>T p.S660F | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as COSV61755010; called by muse, mutect2, varscan2
- USP6 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 59/223 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); catalogued as COSV51499456; called by muse, mutect2, varscan2
- USP6 | c.3304G>A p.E1102K | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.285); catalogued as COSV51499477; called by muse, mutect2, varscan2
- VCL | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139312390; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VEGFA | c.142C>T p.Q48* (on ENST00000523873 / NM_001171623.1; = p.Q228* on NM_003376.6) | Nonsense Mutation (SNP) | VAF 24/54 reads (44%) | catalogued as COSV57880189; called by muse, mutect2, varscan2
- VGLL3 | c.944A>C p.Q315P | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.979); catalogued as COSV68210873; called by muse, mutect2, varscan2
- VPS4B | c.1187G>A p.W396* | Nonsense Mutation (SNP) | VAF 25/119 reads (21%) | catalogued as COSV53071181; called by muse, mutect2, varscan2
- VPS54 | c.1178G>A p.R393K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV55442535, COSV55446348; called by muse, mutect2, varscan2
- WARS2 | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768514641, COSV52483313; called by muse, mutect2, varscan2
- WDR47 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 230/790 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63060295; called by muse, mutect2, varscan2
- WDR49 | c.1166G>A p.G389E (on ENST00000308378 / NM_001366158.1; = p.G730E on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57719497; called by muse, mutect2, varscan2
- WNT2B | c.1009A>G p.I337V (on ENST00000369684 / NM_024494.3; = p.I318V on NM_004185.4) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV56677716; called by muse, mutect2, varscan2
- XYLT2 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs748868891, COSV50023678; called by muse, mutect2, varscan2
- YES1 | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.712); catalogued as COSV58853508; called by muse, mutect2, varscan2
- YLPM1 | c.1816C>T p.P606S | Missense Mutation (SNP) | VAF 81/90 reads (90%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.327); catalogued as COSV53122485; called by muse, mutect2, varscan2
- ZDHHC24 | c.382G>A p.G128S | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs751079398, COSV100130760; called by muse, mutect2, varscan2
- ZFHX3 | c.2144G>A p.R715Q | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs147160019; called by muse, mutect2, varscan2
- ZFHX3 | c.1874C>T p.S625F | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV51739885; called by muse, mutect2, varscan2
- ZFP2 | c.406G>A p.G136R | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV63727219; called by muse, mutect2, varscan2
- ZNF16 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV52766106; called by muse, mutect2, varscan2
- ZNF229 | c.2300C>T p.P767L | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.522); catalogued as COSV52165798, COSV99350585; called by muse, mutect2
- ZNF284 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1291946297, COSV69691843; called by muse, mutect2, varscan2
- ZNF398 | c.1843C>A p.L615I (on ENST00000475153 / NM_170686.3; = p.L444I on NM_020781.4) | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.101); catalogued as COSV60067156; called by muse, mutect2, varscan2
- ZNF451 | c.481C>T p.H161Y | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV62600545; called by muse, mutect2, varscan2
- ZNF462 | c.2758C>T p.H920Y | Missense Mutation (SNP) | VAF 77/84 reads (92%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV52953094; called by muse, mutect2, varscan2
- ZNF521 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs999285894, COSV64132966; called by muse, mutect2, varscan2
- ZNF572 | c.1064C>T p.S355F | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV60002347; called by muse, mutect2, varscan2
- ZNF701 | c.1171C>T p.P391S (on ENST00000301093; = p.P325S on NM_018260.3) | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV56527601; called by muse, mutect2, varscan2
- ZNF831 | c.3646C>T p.L1216F | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.459); catalogued as COSV64046227; called by muse, mutect2
- ZNF85 | c.1733C>T p.S578F | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV60217612; called by muse, mutect2, varscan2
- ZZEF1 | c.8161C>T p.P2721S | Missense Mutation (SNP) | VAF 65/114 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV67560253; called by muse, mutect2, varscan2
- DACH1 | c.1987del p.T663Hfs*15 (on ENST00000619232 / NM_001366712.1; = p.T409Hfs*15 on NM_004392.6) | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | called by pindel, varscan2
- DST | c.7387dup p.A2463Gfs*5 | Frame Shift Ins (INS) | VAF 51/159 reads (32%) | called by mutect2, pindel, varscan2
- IGHG2 | c.172C>T p.Q58* | Nonsense Mutation (SNP) | VAF 22/24 reads (92%) | called by mutect2, varscan2
- KRT82 | c.32G>A p.R11K | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.169); called by muse, mutect2
- NKD1 | c.805_809dup p.Q271Rfs*78 | Frame Shift Ins (INS) | VAF 8/35 reads (23%) | called by mutect2, pindel, varscan2
- POTEF | c.1572A>T p.E524D | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.319); called by mutect2, varscan2
- TPTE | c.358C>A p.L120I (on ENST00000618007 / NM_199261.4; = p.L102I on NM_199259.4) | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.007); called by muse, mutect2
- TRGV8 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- ZNF621 | c.254_257del p.S85Kfs*12 | Frame Shift Del (DEL) | VAF 20/73 reads (27%) | called by mutect2, pindel, varscan2
- ABCC3 | c.2170C>T p.L724= | Silent (SNP) | VAF 30/117 reads (26%) | catalogued as COSV53330891; called by muse, mutect2, varscan2
- ABCC5 | c.4230C>T p.T1410= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as rs1271217172, COSV55594441, COSV99657885; called by muse, mutect2, varscan2
- ABI3 | c.846C>T p.P282= | Silent (SNP) | VAF 46/125 reads (37%) | catalogued as rs771368722, COSV56801735; called by muse, mutect2, varscan2
- ABL1 | c.1545C>T p.V515= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV59336750; called by muse, mutect2, varscan2
- AC109583.1 | c.816G>A p.E272= | Silent (SNP) | VAF 62/229 reads (27%) | catalogued as rs555773656, COSV58406827; called by muse, mutect2, varscan2
- ADAM18 | c.834G>A p.R278= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as rs1384361572, COSV55855040; called by muse, mutect2
- ADAMTSL4 | c.351G>A p.Q117= | Silent (SNP) | VAF 24/126 reads (19%) | catalogued as COSV55008935; called by muse, mutect2, varscan2
- ADCY8 | c.2022C>T p.T674= | Silent (SNP) | VAF 86/176 reads (49%) | catalogued as COSV53932352; called by muse, mutect2, varscan2
- AGBL5 | c.831C>T p.A277= | Silent (SNP) | VAF 70/109 reads (64%) | catalogued as COSV59938034; called by muse, mutect2, varscan2
- ALDH2 | c.348G>A p.R116= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV55672395; called by muse, mutect2, varscan2
- ANKK1 | c.525G>A p.R175= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV58274769; called by muse, mutect2, varscan2
- ANKS1B | c.1836C>T p.S612= | Silent (SNP) | VAF 115/218 reads (53%) | catalogued as COSV61362643; called by muse, mutect2, varscan2
- ANO1 | c.1665C>T p.S555= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as rs1331782374, COSV60290302; called by muse, mutect2
- AOC3 | c.1233G>A p.V411= | Silent (SNP) | VAF 51/74 reads (69%) | catalogued as COSV53829242; called by muse, mutect2, varscan2
- ARFGEF2 | c.3735C>T p.F1245= | Silent (SNP) | VAF 40/83 reads (48%) | catalogued as rs1365027593, COSV64215792; called by muse, mutect2, varscan2
- ARHGAP25 | c.1542G>A p.G514= (on ENST00000409202 / NM_001007231.3; = p.G506= on NM_014882.3) | Silent (SNP) | VAF 26/119 reads (22%) | catalogued as COSV54909023; called by muse, mutect2, varscan2
- ARL14 | c.156C>T p.I52= | Silent (SNP) | VAF 31/99 reads (31%) | catalogued as rs776701439, COSV100296450, COSV57900579; called by muse, mutect2, varscan2
- ATXN10 | c.990G>A p.L330= | Silent (SNP) | VAF 22/101 reads (22%) | catalogued as rs540746311, COSV53301519; called by muse, mutect2, varscan2
- AURKC | c.855C>T p.A285= (on ENST00000302804 / NM_001015878.2; = p.A251= on NM_003160.3) | Silent (SNP) | VAF 38/87 reads (44%) | catalogued as COSV100248942; called by muse, mutect2, varscan2
- AZU1 | c.531G>A p.E177= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV52142893; called by muse, mutect2, varscan2
- BBS12 | c.66C>T p.F22= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs150546366; ClinVar: likely benign; called by muse, mutect2, varscan2
- BSDC1 | c.1239C>T p.S413= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV61982310, COSV61983676; called by muse, mutect2, varscan2
- C3 | c.594C>T p.L198= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as rs763650811, COSV55576347, COSV55582840; called by muse, mutect2, varscan2
- CACNA1E | c.3309G>A p.E1103= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as COSV100702979, COSV62396116; called by muse, mutect2, varscan2
- CACNA1S | c.3189C>T p.F1063= | Silent (SNP) | VAF 54/89 reads (61%) | catalogued as rs150020550, COSV62938093; ClinVar: benign / likely benign / uncertain significance; called by muse, mutect2, varscan2
- CAMK2B | c.330G>A p.E110= | Silent (SNP) | VAF 23/140 reads (16%) | catalogued as COSV51667688; called by muse, mutect2, varscan2
- CAMK2B | c.192C>T p.I64= | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as COSV51667706, COSV99322673; called by muse, mutect2, varscan2
- CAMK4 | c.1272G>A p.G424= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as COSV56685904; called by muse, mutect2, varscan2
- CAPN12 | c.786C>T p.S262= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as rs755247263, COSV61019042; called by muse, mutect2, varscan2
- CAPN13 | c.507G>A p.L169= | Silent (SNP) | VAF 38/65 reads (58%) | catalogued as COSV54436267; called by muse, mutect2, varscan2
- CAPRIN1 | c.234C>T p.Y78= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV58222618; called by muse, mutect2, varscan2
- CASC3 | c.1011C>T p.G337= | Silent (SNP) | VAF 121/204 reads (59%) | catalogued as COSV52867258, COSV52867445; called by muse, mutect2, varscan2
- CATSPERB | c.174C>T p.I58= | Silent (SNP) | VAF 14/20 reads (70%) | catalogued as COSV56436793; called by muse, mutect2, varscan2
- CCDC178 | c.2286G>A p.E762= (on ENST00000383096 / NM_001105528.3; = p.E724= on NM_198995.3) | Silent (SNP) | VAF 34/74 reads (46%) | catalogued as COSV55801970; called by muse, mutect2, varscan2
- CCDC88B | c.280C>T p.L94= | Silent (SNP) | VAF 32/114 reads (28%) | catalogued as COSV57268685; called by muse, mutect2
- CCDC88B | c.1683C>T p.P561= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as rs79231173, COSV57268687; called by muse, mutect2, varscan2
- CCKAR | c.903C>T p.S301= | Silent (SNP) | VAF 34/113 reads (30%) | catalogued as COSV55164523; called by muse, mutect2, varscan2
- CD40LG | c.204G>A p.T68= | Silent (SNP) | VAF 45/50 reads (90%) | catalogued as rs775209130, COSV65699166; called by muse, mutect2, varscan2
- CDC42BPG | c.3027C>T p.T1009= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as rs1373949889, COSV61347666; called by muse, mutect2, varscan2
- CDCP1 | c.1113C>T p.V371= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as COSV56108649; called by muse, mutect2, varscan2
- CDH18 | c.1659G>A p.R553= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs771938347, COSV56969392; called by muse, mutect2, varscan2
- CDH3 | c.1659C>T p.I553= | Silent (SNP) | VAF 33/107 reads (31%) | catalogued as COSV50580908; called by muse, mutect2, varscan2
- CDH6 | c.2136C>T p.V712= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as COSV54080023; called by mutect2, varscan2
- CDH8 | c.276G>A p.G92= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV54906581; called by muse, mutect2, varscan2
- CEACAM18 | c.28C>T p.L10= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV67284443; called by muse, mutect2, varscan2
- CFAP221 | c.1485G>A p.K495= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV99733357; called by mutect2, varscan2
- CHD5 | c.4863G>A p.R1621= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV52426969; called by muse, mutect2, varscan2
- CHIA | c.378C>T p.F126= (on ENST00000343320; = p.F18= on NM_021797.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 84/130 reads (65%) | catalogued as COSV58473958; called by muse, varscan2
- CHST6 | c.756C>T p.I252= | Silent (SNP) | VAF 30/64 reads (47%) | catalogued as COSV60000113; called by muse, mutect2, varscan2
- CMYA5 | c.1665G>A p.V555= | Silent (SNP) | VAF 80/237 reads (34%) | catalogued as COSV71410314; called by muse, mutect2, varscan2
- CRACD | c.2277C>T p.P759= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV51733880; called by muse, mutect2, varscan2
- CTAGE1 | c.111G>A p.T37= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as rs775604113, COSV66944161; called by muse, mutect2, varscan2
- CTSV | c.1004G>A p.*335= | Silent (SNP) | VAF 38/44 reads (86%) | catalogued as rs762798163, COSV52346028; called by muse, mutect2, varscan2
- CTTNBP2 | c.4311C>T p.S1437= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as rs1267887888, COSV50412068; called by muse, mutect2, varscan2
- CUL9 | c.5613C>T p.L1871= | Silent (SNP) | VAF 47/94 reads (50%) | catalogued as COSV52731505, COSV52736080; called by muse, mutect2, varscan2
- CUX1 | c.2332C>T p.L778= | Silent (SNP) | VAF 63/130 reads (48%) | catalogued as rs201526507; called by muse, varscan2
- CUX1 | c.2388C>T p.P796= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV52919083; called by muse, varscan2
- CYP2C19 | c.300C>T p.F100= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as rs774817817, COSV64909645; called by muse, mutect2, varscan2
- CYP4F12 | c.736C>T p.L246= | Silent (SNP) | VAF 49/105 reads (47%) | catalogued as COSV61176466; called by muse, mutect2, varscan2
- DCAF1 | c.1416C>T p.A472= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as rs782128426, COSV60047282; called by muse, mutect2, varscan2
- DCC | c.1425A>G p.R475= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as COSV59143326; called by muse, mutect2, varscan2
- DENND2A | c.399G>A p.R133= | Silent (SNP) | VAF 69/315 reads (22%) | catalogued as COSV52060772; called by muse, mutect2, varscan2
- DENR | c.67T>C p.L23= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV54889623; called by muse, mutect2, varscan2
- DGKD | c.1473C>T p.I491= (on ENST00000264057 / NM_152879.3; = p.I447= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/78 reads (37%) | catalogued as COSV51118762; called by muse, mutect2, varscan2
- DGKD | c.2853C>T p.S951= (on ENST00000264057 / NM_152879.3; = p.S907= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV99897907; called by muse, mutect2, varscan2
- DIP2B | c.2796C>T p.L932= | Silent (SNP) | VAF 33/65 reads (51%) | catalogued as COSV56593676; called by muse, mutect2
- DISP3 | c.2445C>T p.P815= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as rs774437837, COSV53839375; called by muse, mutect2, varscan2
- DNAH3 | c.5733C>T p.I1911= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as rs1359809105, COSV54558212; called by muse, mutect2, varscan2
- DNAH5 | c.3381C>T p.I1127= | Silent (SNP) | VAF 40/75 reads (53%) | catalogued as COSV54203044, COSV54234352; called by muse, mutect2, varscan2
- DNAH9 | c.8430C>T p.I2810= | Silent (SNP) | VAF 62/102 reads (61%) | catalogued as rs1395999675, COSV52381469; called by muse, mutect2, varscan2
- DNAJC5G | c.108C>T p.S36= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs1276684130, COSV99940681; called by muse, mutect2
- DPP6 | c.1374G>A p.G458= (on ENST00000377770 / NM_001364500.2; = p.G396= on NM_001936.5) | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV59599562; called by muse, mutect2, varscan2
- DPPA2 | c.804C>T p.F268= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV72118370; called by muse, mutect2, varscan2
- DUSP15 | c.759C>T p.S253= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV54068816; called by muse, mutect2, varscan2
- EDC4 | c.2742C>T p.S914= | Silent (SNP) | VAF 38/155 reads (25%) | catalogued as rs753091336, COSV59302020; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2550C>T p.F850= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as rs1390637047, COSV62571461; called by muse, varscan2
- EHD2 | c.534C>T p.F178= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as rs1381489142, COSV54406762; called by muse, mutect2, varscan2
- ENOX1 | c.1308C>T p.L436= | Silent (SNP) | VAF 32/114 reads (28%) | catalogued as rs746764315, COSV54922222; called by muse, mutect2, varscan2
- EPHA7 | c.924C>T p.S308= | Silent (SNP) | VAF 52/63 reads (83%) | catalogued as COSV65193601; called by muse, mutect2, varscan2
- ESCO1 | c.2133C>T p.F711= | Silent (SNP) | VAF 41/183 reads (22%) | catalogued as COSV52519812; called by muse, mutect2, varscan2
- FABP1 | c.165G>A p.G55= | Silent (SNP) | VAF 139/254 reads (55%) | catalogued as COSV55559700, COSV99860997; called by muse, mutect2, varscan2
- FAM237A | c.57C>T p.S19= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV101405609; called by muse, mutect2
- FAM98C | c.12G>A p.V4= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs1184998203, COSV53040053; called by mutect2, varscan2
- FAT3 | c.2364C>T p.P788= | Silent (SNP) | VAF 390/672 reads (58%) | catalogued as COSV53186687; called by muse, mutect2, varscan2
- FAT4 | c.10794C>T p.S3598= | Silent (SNP) | VAF 33/120 reads (28%) | catalogued as COSV58713133; called by muse, mutect2, varscan2
- FCGR2C | c.633C>T p.I211= | Silent (SNP) | VAF 15/116 reads (13%) | catalogued as COSV63442834; called by muse, mutect2, varscan2
- FCRL5 | c.735C>T p.F245= | Silent (SNP) | VAF 64/331 reads (19%) | catalogued as COSV62521225; called by muse, mutect2, varscan2
- FECH | c.624A>G p.R208= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV50493540; called by muse, mutect2, varscan2
- FGF5 | c.669G>A p.E223= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV56892440; called by muse, varscan2
- FLG | c.6489C>T p.H2163= | Silent (SNP) | VAF 107/805 reads (13%) | catalogued as COSV100911625, COSV64251643; called by muse, mutect2, varscan2
- FLT4 | c.360C>T p.I120= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs555609601, COSV56102410, COSV56110561; called by muse, mutect2, varscan2
- FOXO1 | c.1905G>A p.V635= | Silent (SNP) | VAF 31/107 reads (29%) | catalogued as rs1487231302, COSV65429260; called by muse, mutect2, varscan2
- FREM1 | c.3396C>T p.S1132= | Silent (SNP) | VAF 42/94 reads (45%) | catalogued as COSV66530127; called by muse, mutect2, varscan2
- FZD2 | c.1299C>T p.A433= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as rs749699341, COSV59528074; called by muse, mutect2, varscan2
- GABRB2 | c.996G>A p.G332= | Silent (SNP) | VAF 34/126 reads (27%) | catalogued as rs762087070, COSV50959878; ClinVar: likely benign; called by muse, mutect2, varscan2
- GFM2 | c.483T>G p.G161= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV57193847; called by muse, mutect2, varscan2
- GIMAP5 | c.654C>T p.F218= | Silent (SNP) | VAF 27/100 reads (27%) | catalogued as rs1208435748, COSV57530614; called by muse, mutect2, varscan2
- GPR108 | c.732C>T p.I244= (on ENST00000264080 / NM_001080452.1; = p.I2= on NM_020171.2) | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV51188598; called by muse, mutect2
- GPR83 | c.1218C>T p.L406= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV54721266; called by muse, mutect2, varscan2
- GPRC6A | c.1041C>T p.P347= | Silent (SNP) | VAF 48/55 reads (87%) | catalogued as COSV59956522; called by muse, mutect2, varscan2
- GRIK3 | c.2100G>A p.K700= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV66137276; called by muse, mutect2, varscan2
- GRK3 | c.1527C>T p.F509= | Silent (SNP) | VAF 54/57 reads (95%) | catalogued as COSV60801241; called by muse, mutect2, varscan2
- GRXCR2 | c.429G>A p.R143= | Silent (SNP) | VAF 51/61 reads (84%) | catalogued as COSV65062046; called by muse, mutect2, varscan2
- GSDMA | c.279G>A p.V93= | Silent (SNP) | VAF 77/118 reads (65%) | catalogued as rs1397437139, COSV100053648, COSV56980443; called by muse, mutect2, varscan2
- HCAR2 | c.711C>T p.A237= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs1311494710, COSV100186689; called by mutect2, varscan2
- HECTD4 | c.10365C>T p.P3455= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs755586384, COSV66396275; called by muse, mutect2, varscan2
- HERC1 | c.4338C>T p.I1446= | Silent (SNP) | VAF 38/97 reads (39%) | catalogued as COSV101497084; called by muse, mutect2, varscan2
- HHIPL2 | c.1737C>T p.F579= | Silent (SNP) | VAF 75/385 reads (19%) | catalogued as COSV58568450; called by muse, mutect2, varscan2
- HSPA4L | c.285T>G p.P95= | Silent (SNP) | VAF 40/65 reads (62%) | catalogued as COSV56549201; called by muse, mutect2, varscan2
- IGF2R | c.5961C>T p.C1987= | Silent (SNP) | VAF 45/53 reads (85%) | catalogued as COSV63633629; called by muse, mutect2, varscan2
- IGSF10 | c.2094C>T p.L698= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV56793244; called by muse, mutect2, varscan2
- IGSF9B | c.3042G>A p.E1014= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as COSV58071145; called by muse, mutect2, varscan2
- IL12B | c.223C>T p.L75= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV51456311; called by muse, mutect2, varscan2
- INSR | c.2223C>T p.F741= | Silent (SNP) | VAF 68/372 reads (18%) | catalogued as rs1426360966, COSV57175006; called by muse, mutect2, varscan2
- IP6K2 | c.990C>T p.S330= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV53664276; called by muse, mutect2, varscan2
- JCAD | c.3981G>A p.R1327= | Silent (SNP) | VAF 37/92 reads (40%) | catalogued as COSV64762105; called by muse, mutect2, varscan2
- KATNAL1 | c.1168C>T p.L390= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as rs769228528, COSV66065161; called by muse, mutect2, varscan2
- KCNE3 | c.229C>T p.L77= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV100035537; called by muse, mutect2, varscan2
- KCNH7 | c.1593C>T p.L531= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV59817245; called by muse, mutect2, varscan2
- KIDINS220 | c.1515C>T p.T505= | Silent (SNP) | VAF 33/119 reads (28%) | catalogued as COSV56760456; called by muse, mutect2, varscan2
- KIF18B | c.1188C>T p.P396= | Silent (SNP) | VAF 44/161 reads (27%) | catalogued as COSV59273917; called by muse, mutect2, varscan2
- KLHL7 | c.408T>C p.F136= (on ENST00000339077 / NM_001031710.3; = p.F88= on NM_018846.5) | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as COSV59165355; called by muse, mutect2, varscan2
- KLK7 | c.405C>T p.S135= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV100304524, COSV58344075; called by muse, mutect2, varscan2
- KRT6B | c.1662C>T p.T554= | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as rs1356974000, COSV52887087; called by muse, mutect2, varscan2
- LAGE3 | c.417C>T p.P139= | Silent (SNP) | VAF 10/13 reads (77%) | catalogued as COSV62074521; called by muse, mutect2, varscan2
- LDLRAD3 | c.735G>A p.Q245= | Silent (SNP) | VAF 25/101 reads (25%) | catalogued as rs769576610, COSV59678473, COSV59690235; called by muse, mutect2, varscan2
- LHFPL5 | c.579C>T p.S193= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV64178895; called by muse, mutect2, varscan2
- LIMCH1 | c.1497C>T p.F499= | Silent (SNP) | VAF 197/318 reads (62%) | catalogued as COSV58289766, COSV58291429; called by muse, mutect2, varscan2
- LPCAT2 | c.1266C>T p.V422= | Silent (SNP) | VAF 31/96 reads (32%) | catalogued as COSV50901091; called by muse, mutect2, varscan2
- LRG1 | c.727C>T p.L243= | Silent (SNP) | VAF 164/451 reads (36%) | catalogued as COSV56706415; called by muse, mutect2, varscan2
- LRP1B | c.12219C>T p.P4073= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as COSV67284292; called by muse, mutect2, varscan2
- LRRC41 | c.1986G>A p.E662= | Silent (SNP) | VAF 25/113 reads (22%) | catalogued as COSV58442849; called by muse, mutect2, varscan2
- MAGEC1 | c.180G>C p.G60= | Silent (SNP) | VAF 22/32 reads (69%) | catalogued as COSV53568033, COSV99596822; called by muse, mutect2
- MAGEE2 | c.252C>T p.V84= | Silent (SNP) | VAF 32/32 reads (100%) | catalogued as COSV64898679; called by muse, mutect2, varscan2
- MAPK8IP3 | c.2700G>A p.E900= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV51728420; called by muse, mutect2, varscan2
- MARCHF2 | c.549C>T p.I183= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as rs755249321, COSV53106036; called by mutect2, varscan2
- ME3 | c.1290C>T p.A430= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV62773034; called by muse, mutect2, varscan2
- MED12L | c.2190C>T p.L730= | Silent (SNP) | VAF 80/262 reads (31%) | catalogued as COSV56383714, COSV56400859; called by muse, mutect2, varscan2
- MED12L | c.6213C>T p.P2071= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV56400864, COSV56401631; called by muse, mutect2, varscan2
- MGAM | c.2583G>A p.T861= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs1334712003, COSV72074155; called by muse, mutect2, varscan2
- MGAM | c.2997C>T p.V999= | Silent (SNP) | VAF 85/202 reads (42%) | catalogued as COSV72076117; called by muse, mutect2, varscan2
- MGAT5B | c.876C>T p.F292= | Silent (SNP) | VAF 38/107 reads (36%) | called by muse, mutect2, varscan2
- MRGPRX1 | c.60G>A p.E20= | Silent (SNP) | VAF 58/209 reads (28%) | catalogued as COSV57110193; called by muse, mutect2, varscan2
- MRO | c.321C>T p.I107= | Silent (SNP) | VAF 37/78 reads (47%) | catalogued as COSV56498988; called by muse, mutect2, varscan2
- MROH7 | c.2700C>T p.F900= | Silent (SNP) | VAF 36/60 reads (60%) | catalogued as rs748539243, COSV59879253; called by muse, mutect2, varscan2
- MUC16 | c.26481G>A p.G8827= | Silent (SNP) | VAF 29/127 reads (23%) | catalogued as COSV67500943; called by muse, mutect2, varscan2
- MYH1 | c.5544G>A p.E1848= | Silent (SNP) | VAF 56/109 reads (51%) | catalogued as COSV56858663, COSV99874796; called by muse, mutect2, varscan2
- MYH1 | c.2241G>A p.E747= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV56858671; called by muse, mutect2, varscan2
- MYH7B | c.5619G>A p.E1873= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs756659081, COSV52685311; called by muse, mutect2, varscan2
- MYO18A | c.2295C>T p.T765= | Silent (SNP) | VAF 32/48 reads (67%) | catalogued as rs779263099, COSV62874919; called by muse, mutect2, varscan2
- MYO3B | c.3144C>T p.Y1048= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV58720923; called by muse, mutect2, varscan2
- MYO5C | c.1653T>C p.F551= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as COSV55913001; called by muse, mutect2, varscan2
- NEB | c.6033C>T p.P2011= | Silent (SNP) | VAF 88/246 reads (36%) | catalogued as rs773482640, COSV51466971; ClinVar: uncertain significance / likely benign; called by muse, varscan2
- NEFH | c.1665G>A p.K555= | Silent (SNP) | VAF 37/43 reads (86%) | catalogued as rs775140815, COSV60221326; called by muse, mutect2, varscan2
- NEUROD4 | c.828C>T p.S276= | Silent (SNP) | VAF 46/208 reads (22%) | catalogued as COSV54474350, COSV54474648; called by muse, mutect2, varscan2
- NFE2 | c.228C>T p.F76= | Silent (SNP) | VAF 37/128 reads (29%) | catalogued as rs757340044, COSV56457679; called by muse, mutect2, varscan2
- NLRP13 | c.777G>A p.Q259= | Silent (SNP) | VAF 66/136 reads (49%) | catalogued as COSV61624448; called by muse, mutect2, varscan2
- NLRP6 | c.1299C>T p.A433= | Silent (SNP) | VAF 84/132 reads (64%) | catalogued as COSV100381247; called by muse, mutect2, varscan2
- NOS1 | c.3474C>T p.F1158= | Silent (SNP) | VAF 30/131 reads (23%) | catalogued as COSV57606346; called by muse, mutect2, varscan2
- NOTCH4 | c.2466G>A p.Q822= | Silent (SNP) | VAF 65/237 reads (27%) | catalogued as COSV100901232; called by muse, mutect2, varscan2
- NOTUM | c.1425G>A p.Q475= | Silent (SNP) | VAF 46/156 reads (29%) | catalogued as COSV68826813; called by mutect2, varscan2
- NR5A2 | c.1062C>T p.F354= (on ENST00000367362 / NM_205860.3; = p.F308= on NM_003822.5) | Silent (SNP) | VAF 31/211 reads (15%) | catalogued as COSV99371817; called by muse, mutect2, varscan2
- NUP210 | c.3630C>T p.F1210= | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as COSV54415372; called by muse, mutect2, varscan2
- NUP214 | c.1641C>T p.S547= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV63913701; called by muse, mutect2, varscan2
- NWD1 | c.2061G>A p.G687= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs779449587, COSV60353596; called by muse, mutect2, varscan2
- OR10S1 | c.790C>T p.L264= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as rs1250063677, COSV73343083; called by muse, mutect2, varscan2
- OR13A1 | c.645C>T p.V215= | Silent (SNP) | VAF 36/41 reads (88%) | catalogued as COSV65573691; called by muse, mutect2, varscan2
- OR1L1 | c.468C>T p.A156= (on ENST00000373686; = p.A106= on NM_001005236.3) | Silent (SNP) | VAF 54/131 reads (41%) | catalogued as rs776205424, COSV58936965; called by muse, mutect2, varscan2
- OR2T35 | c.627C>A p.I209= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as rs547447054; called by mutect2, varscan2
- OR51A4 | c.357C>T p.I119= | Silent (SNP) | VAF 64/290 reads (22%) | catalogued as rs868190793, COSV66750182; called by muse, mutect2, varscan2
- OR51T1 | c.243C>T p.P81= | Silent (SNP) | VAF 29/78 reads (37%) | catalogued as COSV59028575; called by muse, mutect2, varscan2
- OR5T2 | c.909C>T p.S303= | Silent (SNP) | VAF 33/122 reads (27%) | catalogued as COSV57591543; called by muse, mutect2, varscan2
- OR6C2 | c.765C>T p.F255= | Silent (SNP) | VAF 28/99 reads (28%) | catalogued as rs868046785, COSV59515850; called by muse, mutect2, varscan2
- OR6T1 | c.54C>T p.P18= | Silent (SNP) | VAF 35/120 reads (29%) | catalogued as COSV58310015; called by muse, mutect2, varscan2
- OR8D1 | c.171C>T p.T57= | Silent (SNP) | VAF 39/69 reads (57%) | catalogued as rs746084280, COSV100766690; called by muse, mutect2, varscan2
- PADI6 | c.1668G>A p.K556= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV61885998; called by muse, mutect2, varscan2
- PARP15 | c.951G>A p.Q317= (on ENST00000464300 / NM_001113523.3; = p.Q83= on NM_152615.2) | Silent (SNP) | VAF 64/108 reads (59%) | catalogued as COSV59975458; called by muse, varscan2
- PCSK7 | c.1401C>T p.L467= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as COSV58008884, COSV58009875; called by muse, mutect2, varscan2
- PDZD2 | c.4425C>T p.V1475= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs762213817, COSV56875741; called by muse, mutect2, varscan2
- PDZD3 | c.1236G>A p.E412= (on ENST00000531114; = p.E332= on NM_024791.4) | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs12292621, COSV52710665; called by muse, mutect2, varscan2
- PEG3 | c.1815G>A p.G605= | Silent (SNP) | VAF 29/47 reads (62%) | catalogued as rs1328306993, COSV55634097; called by muse, mutect2, varscan2
- PHKA1 | c.649C>T p.L217= | Silent (SNP) | VAF 7/8 reads (88%) | catalogued as COSV59805007, COSV59812732; called by muse, mutect2, varscan2
- PLB1 | c.2283C>T p.L761= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV100215588; called by muse, mutect2, varscan2
- PLD2 | c.357C>T p.V119= | Silent (SNP) | VAF 53/216 reads (25%) | catalogued as COSV54010769; called by muse, mutect2, varscan2
- PLIN4 | c.2511G>A p.L837= (on ENST00000301286; = p.L852= on NM_001367868.2) | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as COSV56700182; called by muse, varscan2
- PLXNA4 | c.2709T>A p.P903= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as COSV58166089; called by muse, mutect2, varscan2
- PML | c.327C>T p.F109= | Silent (SNP) | VAF 39/70 reads (56%) | catalogued as rs1185807473, COSV51455588; called by muse, mutect2, varscan2
- PNPLA6 | c.2283C>T p.F761= (on ENST00000414982 / NM_001166111.2; = p.F713= on NM_006702.5) | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV55386675; called by muse, mutect2, varscan2
- PPP1R7 | c.729C>T p.T243= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV52147459; called by muse, mutect2, varscan2
- PRAMEF12 | c.324G>A p.V108= | Silent (SNP) | VAF 178/285 reads (62%) | catalogued as COSV63215092; called by muse, mutect2, varscan2
- PREX1 | c.2691C>T p.F897= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs763619070, COSV64247734; called by mutect2, varscan2
- PREX1 | c.1608G>A p.L536= | Silent (SNP) | VAF 29/121 reads (24%) | catalogued as COSV64257711; called by muse, mutect2, varscan2
- PRMT3 | c.1326C>T p.I442= | Silent (SNP) | VAF 47/75 reads (63%) | catalogued as COSV58181488; called by muse, mutect2, varscan2
- PTPRT | c.2190G>A p.Q730= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV62006170; called by muse, mutect2, varscan2
- PXDN | c.1008C>T p.F336= | Silent (SNP) | VAF 40/164 reads (24%) | catalogued as rs374531463, COSV53227863; called by muse, mutect2, varscan2
- PYGM | c.975G>A p.T325= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as rs747106887, COSV51231740; ClinVar: likely benign; called by muse, mutect2, varscan2
- RAD51AP2 | c.1428T>A p.T476= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV67589444; called by muse, mutect2, varscan2
- RBBP8 | c.981T>A p.S327= | Silent (SNP) | VAF 40/144 reads (28%) | catalogued as COSV59096637; called by mutect2, varscan2
- RELL1 | c.261T>C p.R87= | Silent (SNP) | VAF 48/159 reads (30%) | catalogued as COSV58455436; called by muse, mutect2, varscan2
- RHOA | c.324C>T p.P108= | Silent (SNP) | VAF 55/86 reads (64%) | catalogued as rs749741822, COSV69042250; called by muse, mutect2, varscan2
- ROCK2 | c.849C>T p.F283= | Silent (SNP) | VAF 32/164 reads (20%) | catalogued as COSV55076125; called by muse, mutect2, varscan2
- RP1L1 | c.6972G>A p.R2324= | Silent (SNP) | VAF 75/187 reads (40%) | catalogued as rs867576810, COSV66761337; called by muse, mutect2, varscan2
- RPF2 | c.765C>T p.S255= | Silent (SNP) | VAF 42/47 reads (89%) | catalogued as rs1162324098, COSV64371094; called by muse, mutect2, varscan2
- RPS18 | c.123T>G p.A41= | Silent (SNP) | VAF 57/257 reads (22%) | catalogued as COSV65852278; called by muse, mutect2, varscan2
- RTN2 | c.681G>A p.S227= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs1299159641, COSV55596533; called by muse, mutect2, varscan2
- RYR3 | c.705G>A p.T235= | Silent (SNP) | VAF 53/159 reads (33%) | catalogued as rs368203752; called by muse, mutect2, varscan2
- S1PR1 | c.873C>T p.F291= | Silent (SNP) | VAF 69/236 reads (29%) | catalogued as COSV59513477; called by muse, mutect2, varscan2
- SAFB2 | c.2509C>T p.L837= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV53042715; called by muse, mutect2
- SEL1L3 | c.2106G>C p.G702= | Silent (SNP) | VAF 31/93 reads (33%) | catalogued as COSV53550957; called by muse, mutect2, varscan2
- SEPTIN12 | c.441C>T p.I147= | Silent (SNP) | VAF 27/117 reads (23%) | catalogued as COSV51619287; called by muse, mutect2, varscan2
- SEPTIN3 | c.534C>T p.I178= | Silent (SNP) | VAF 54/55 reads (98%) | catalogued as COSV52174404; called by muse, mutect2, varscan2
- SERPINA7 | c.243C>T p.S81= | Silent (SNP) | VAF 19/21 reads (90%) | catalogued as COSV59667659; called by muse, mutect2, varscan2
108 further variants in this file (0 protein-altering or splice-affecting, 88 silent, 20 other) are not listed here.
